Gene-level copy-number profile of tumor specimen TCGA-CV-5441-01A from TCGA case TCGA-CV-5441, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.3 years (21,305 days).
Specimen TCGA-CV-5441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.7e59dedd-121e-4c33-ba27-37ddb4ff65be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5441-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/300d4be8-e029-415b-b2ef-47e49ac606ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,956; copy number 2: 44,618; copy number 3: 4,202; copy number 4: 1,570; copy number 5: 878; copy number 6: 104; copy number 8: 482.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5441-01A-01D-1510-01): tumor purity 0.63, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,464 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:115,358,498–170,738,536, 868 genes, copy number 5 (broad region; genes not listed).
- chr10:4,650,158–4,848,062, 4 genes, copy number 5 (within-gene range 3–5): MANCR, LINC00705, AC018978.1, AKR1E2.
- chr11:56,252,254–56,989,867, 52 genes, copy number 6: OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P, OR5AP1P, OR5AP2, OR5AR1, OR2AH1P, TMEM230P2, OR9G1, AP001803.1, OR9G3P, OR9G4, MIR6128, AP001803.10, OR9G2P, OR5G1P, OR5G4P, OR5G5P, OR5G3, LINC02735, FADS2B, OR5AK3P, OR5AK2.
- chr11:69,000,765–73,598,189, 158 genes, copy number 6–8 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 8 (broad region; genes not listed).
- chr20:16,670,641–16,864,148, 6 genes, copy number 5: Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1.

Autosomal genes at a single copy (total copy number 1): 5,535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
